Surgical pathology report (de-identified scan), TCGA case TCGA-24-1850, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1850-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT
FINAL

DIAGNOSIS:

OVARY, LEFT, OOPHORECTOMY

- HIGH GRADE SEROUS CARCINOMA
- PARAOVARIAN ADHESIONS

FALLOPIAN TUBE, LEFT, SALPINGECTOMY

- FALLOPIAN TUBE WITH HIGH GRADE SEROUS CARCINOMA INVADING INTO BUT NOT THROUGH THE MUSCULARIS WITH SURROUNDING IN SITU SEROUS CARCINOMA

OVARY, RIGHT, OOPHORECTOMY

- HIGH GRADE SEROUS CARCINOMA WITH SURFACE INVOLVEMENT
- EXTENSIVE LYMPHVASCULAR SPACE INVASION
- PARAOVARIAN SIMPLE CYST

FALLOPIAN TUBE, RIGHT, SALPINGECTOMY

- PARATUBAL CYSTS

UTERUS, SEROSA, TOTAL ABDOMINAL HYSTERECTOMY

- HIGH GRADE SEROUS CARCINOMA WITH EXTENSION INTO MYOMETRIUM
- FOCAL ENDOSALPINGIOSIS

UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- HIGH GRADE SEROUS CARCINOMA INVADING INTO THE MYOMETRIUM BY DIRECT EXTENSION FROM SEROSAL IMPLANT
- EXTENSIVE LYMPHVASCULAR SPACE INVASION
- LEIOMYOMATA (LARGEST MEASURING 3.5 CM IN MAXIMUM DIMENSION)
- DETACHED CALCIFIED AND HYALINIZED LEIOMYOMA

UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY

- HIGH GRADE SEROUS CARCINOMA INVOLVING PARAMETRIAL/PERITONEAL TISSUE
- LYMPHOVASCULAR SPACE INVASION IN DEEP CERVICAL SOFT TISSUE

OMENTUM, OMENTECTOMY

- HIGH GRADE SEROUS CARCINOMA
- NO CARCINOMA IDENTIFIED IN ONE LYMPH NODE (0/1)

LYMPH NODES, SITE NOT SPECIFIED, EXCISION

- METASTATIC CARCINOMA PRESENT IN ONE OF THREE LYMPH NODES (1/3)

[page 2 of 4]
TCGA-24-1850

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By

Intraoperative Consultation:

"Brought to frozen 'left tube and ovary' consisting of a 275 gram specimen measuring 12.5 x 7 x 5 cm. It has a smooth outer lining. Sectioned to release serous fluid and to show a unilocular cyst with smooth lining and no papillary excrescences. Two yellow-tan, firm plaques are present and frozen as FS1. Tumor and normal fallopian tube taken for study. Remainder for permanents," by

FS: Left tube and ovary, biopsy

- "High grade serous adenocarcinoma," by

Microscopic Description and Comment:

Within the left fallopian tube, there is a 0.8 cm focus of invasive serous carcinoma surrounded by areas of in situ serous carcinoma. The serous carcinoma invades into the muscularis but not through the wall of the tube. There is also a large amount of morphologically identical serous carcinoma involving both ovaries, the serosa of the uterus, the parametrial soft tissue, the omentum and a lymph node from an unspecified site. Focally the tumor in these areas shows cleared cytoplasm suggestive of a clear cell carcinoma component, but these areas make up much less than 10% of the tumor.

The presence of in situ serous carcinoma adjacent to invasive serous carcinoma in the left fallopian tube is strong evidence that there is a primary fallopian tube carcinoma. Whether the tumor in the ovaries and peritoneum are metastatic from this fallopian tube carcinoma or represent synchronous primary tumors cannot be determined with certainty.

History:

The patient is a with a pelvic mass, omental mass, and elevated CA125 level.

Specimen(s) Received:

A: LEFT OVARY AND TUBE

B: RIGHT TUBE AND OVARY, UTERUS AND CERVIX

C: OMENTUM

Gross Description:

The specimens are received in three formalin-filled containers, each labeled. The first container is labeled "left tube and left ovary." It contains a previously sectioned cystic ovary with the previously described dimensions and weight as stated in the intraoperative portion of this report. The serosal surface of the cystic ovary is tan-yellow and purple. There are a few fibrous adhesions noted on the surface of the cyst covering an area of 6 x 4 cm. The inner surface of the cyst is relatively smooth and has a similar coloration as the outer surface. There is an intramural, nodular thickening measuring 2.5 x 1.8 x 0.9 cm. It has been previously sectioned to reveal a yellow-tan and white cut surface which is variegated. There is another thickened area of the wall of the cyst measuring 1.8 x 2.9 x 1.5 cm. This may represent a portion of the round ligament vs residual ovary. It is sectioned to show a yellow-tan to white, variegated cut surface. There is an attached fallopian tube measuring 4.2 cm in length x 0.8 cm in average

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

diameter. It appears to have been previously ligated. The serosal surface contains a yellow-tan, nodular tumor implant measuring 2.4 x 2.8 x 2.4 cm. It is located at the distal end of the fallopian tube and involves the fimbria. The cystic ovarian mass appears to be separate from the fallopian tube. A remnant of the ovary is not grossly identifiable. There is an additional segment of fallopian tube noted measuring 1 cm in length with a diameter of 0.4 cm. It has a pinpoint lumen and contains no lesions. Serial sectioning through the remainder of the fallopian tube reveals tumor within the lumen contiguous with the previously described tumor implant on the surface of the fallopian tube. Proximal to the tumor, the fallopian tube appears somewhat dilated and filled with serosanguineous fluid. The lumen measures up to 0.6 cm in diameter. Also present within the container is a white tissue cassette labeled "FS1." It contains fragments of tan-yellow soft tissue, measuring 2.2 x 1.5 x 0.2 cm in aggregate.

Labeled: A1 - remnant of FS1; A2 to A4, nodular thickened area of cyst wall, entirely submitted; A5, the other nodule located within the cyst wall, possibly representing round ligament; A6, probable fibrous adhesions on surface of cyst; A7, additional sections of cyst; A8, small segment of fallopian tube located most proximally; A9 and A10, more proximal end of additional segment of fallopian tube distal to point of ligation; A11 and A12, cyst wall in relation to fallopian tube and tumor nodule on fallopian tube surface; A13, tumor nodule at fimbriated end of fallopian tube; A14, cyst wall and paraovarian tissue.

The second container is labeled "right tube and ovary, uterus, and cervix." It contains a uterus and cervix with attached proximal portion of right fallopian tube. The uterus and cervix measure 7 cm from fundus to tip of cervix x 6.3 cm from cornu to cornu x 6 cm from anterior to posterior. The serosal surface of the uterus is tan-pink to purple. There are possible tumor implants noted on the posterior right aspect of the fundus, measuring 2.3 x 1.5 x 0.4 cm. The anterior and posterior fundic aspects of the uterus are nodular due to the presence of subserosal and intramural probable leiomyomas. The cervix measures 3.5 x 3.4 x 3.4 cm. The left and posterior parametria appear to contain tumor implants, measuring up to 3.7 x 2.3 x 3 cm. A portion of the peritoneal lining over the posterior aspect of the uterus and parametria has been partially pulled away from the parametria and uterus. There is redundant peritoneal tissue which may actually be a portion of a cystic structure which has been previously opened. The exact size of this possible cystic structure cannot be determined. This portion of redundant peritoneal tissue vs cyst wall tissue measures 3 cm in greatest dimension with a thickness measuring up to 0.3 cm. The ectocervix measures 3.4 x 3 x 4 cm and is tan-pink to purple and unremarkable. The cervical os is slit-like and measures ~0.7 cm. The uterus and cervix are opened to reveal an endometrial cavity measuring 2 x 3 cm. The endometrial cavity is somewhat deformed due to the presence of a submucosal, probable leiomyoma within the anterior superior segment as well as other intramural and subserosal leiomyomas. These leiomyomas range in size from 1.5 to 3.5 cm in greatest dimension. They have discrete borders and tan-white, whorled cut surfaces. The endometrial mucosa is tan-pink to red without lesions and measures up to 1 mm in thickness. The endocervical canal measures 2.7 x 0.7 cm with tan-white mucosa with a herringbone contour. Also present within the container is an ovary with attached segment of fallopian tube. The presumed right ovary is previously disrupted with an opening in the serosa with readily observable tumor. Though it is rather difficult to reconstruct the original dimensions of the ovary, the ovary appears to measure 6 x 3.5 x 3.4 cm. The serosal surface is tan, grey, purple, and pink and yellow. There may be possible tumor implants on the serosa which measure <1 mm in height. Sectioning through the right ovary reveals solid tumor making up 50% of the ovary as well as a cyst measuring 2.5 cm in diameter. The cyst is filled with tan-yellow to grey, papillary excrescences along with blood. The more solid component has a variegated, tan-grey and yellow cut surface. The right fallopian tube measures 5.4 cm in length with a diameter ranging from 0.5 to 2 cm at the fimbriated end. The serosal surface is tan-grey to purple and unremarkable. Sectioning the fallopian tube reveals a pinpoint lumen with a wall thickness measuring up to 0.2 cm. The tumor does not appear to involve the fallopian tube grossly. There are multiple paratubal cysts ranging in size from 0.4 to 0.7 cm in diameter located between the fallopian tube and the ovarian mass. The cysts have a smooth inner lining and contain clear fluid. Also present within the container are multiple fragments of grey-tan, soft tissue fragments with ragged surfaces, measuring 3.5 x 3.5 x 1.5 cm in aggregate. They are sectioned to show yellow-tan and grey, variegated cut surfaces similar to the tumor previously described in other areas. There is a round, hard structure with a tan-white and purple surface measuring 1.2 x 0.8 x 0.8 cm. It is sectioned to show a tan-yellow, variegated cut surface. Also present within the container are fragments of possible serosal tissue vs cyst wall, measuring 3.7 x 3.5 x 0.4 cm in aggregate. They are sectioned to show grey, as well as grey, yellow, variegated cut surfaces. Also present within the container is a fragment of yellow, maroon, and grey, fibrofatty soft tissue measuring 4.7 x 3.5 x 1 cm. Within this tissue one possible lymph node is identified measuring 3.9 x 0.8 x 0.5 cm.

Labeled B1, possible tumor implant on uterine serosal surface; B2, redundant peritoneum vs possible cyst wall located on posterior aspect of parametria; B3 to B5, contiguous strip of anterior endomyometrium including cervix to fundus; B6 to B8, contiguous strip of posterior endomyometrium including cervix to fundus; B9, left parametrium; B10, right parametrium; B11, additional posterior parametrium; B12, probable leiomyomas; B13 to B17, right ovarian mass; B18, right ovarian mass in relation to paratubal cyst; B19, right fallopian tube and paraovarian tissue; B20, fimbriated end of right fallopian tube; B21, detached fragments of possible tumor; B22, hard nodule (for decalcification); B23, detached fragments of serosa vs cyst wall; B24, one possible lymph node bisected; B25, remainder of fibrofatty tissue

[page 4 of 4]
TCGA-24-1850

SURGICAL PATHOLOGY REPORT

surrounding possible lymph node. [REDACTED]

The third container is labeled "omentum." It contains a portion of omentum measuring 32.5 x 7.5 x 4.5 cm. The omentum is yellow and purple and contains two probable tumor implants, the largest of which measures 7.5 x 6 x 4.5 cm. The largest tumor implant is a cystic structure, which upon opening, contains serosanguineous fluid. The cyst wall is tan, pink, purple, and yellow with a fairly smooth outer surface. The inner lining contains papillary excrescences measuring up to 4 cm in greatest dimension. The cystic structure is multiloculated. The smaller implant measures 2.3 x 1.4 x 1.6 cm. Labeled C1 to C3, larger cystic tumor implant; C4, smaller tumor implant. [REDACTED]

Source: NCI Genomic Data Commons file 15433ec7-87e4-4bd5-8020-e018bd672ad3 (TCGA-24-1850.A8C2F09F-6971-48E1-B890-F1D63611CDBD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).